Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V8, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V8-01A (Primary Tumor).

[page 1 of 5]
Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

year old with right thyroid nodule, FNA showing PTC.

Specimens Submitted:

- 1: Right paratracheal node (fs)
- 2: To rule out right lower parathyroid (fs)
- 3: Rule out right upper parathyroid (fs)
- 4: Right superior mediastinal lymph node (fs)
- 5: Lymph node lateral to the right RLN (fs)
- 6: Right levels 3 and 4 lymph nodes, neck
- 7: Total thyroidectomy
- 8: Rule out right lower parathyroid

DIAGNOSIS:

1. Paratracheal, right, lymph node ; biopsy(fs):
-Metastatic papillary thyroid carcinoma to three of three lymph nodes (3/3). The largest metastatic node is 0.6 cm in greatest size and completely replaced by tumor. No extra-nodal extension seen.
2. Parathyroid, right, lower; biopsy(fs):
-Benign thymic tissue.
3. Parathyroid, right upper ; biopsy(fs):
-Benign parathyroid tissue.
4. mediastinum, right, superior, lymph node, excision(fs):
-Metastatic papillary thyroid carcinoma to one of one lymph node. The metastatic node is 0.8 cm in greatest size and completely replaced by tumor. Extra-nodal extension is seen.
5. Lymph node, lateral to the right recurrent laryngeal nerve, excision (fs):
- Metastatic papillary thyroid carcinoma to one of one lymph node. The metastatic node is 0.3 cm in greatest size and completely replaced by tumor. Extra-nodal extension is seen.
6. Right levels 3 and 4 lymph nodes, neck:
Part # 6
Lymph Node Dissection:
Metastatic papillary carcinoma of thyroid
Number of lymph nodes examined: 10
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 1.7cm.
Size of the largest metastatic focus : 1.2 cm.
Extranodal extension is not identified

ICD-O-3

Carcinoma, papillary, tall cell

8344/3

Site: Thyroid, NOS

C73.9

5-2-12

20

[page 2 of 5]
7. Total thyroidectomy:

Part # 7

Tumor Type:

Papillary carcinoma, tall cell variant $\geq 50\%$ Tall cell features per TBS *fu*

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.5 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: peri-thyroid fibroadipose tissue

Surgical Margins:

Tumor is present at the anterior margin.

Tumor Multicentricity:

Separate focus of papillary microcarcinoma in right lobe (0.3 cm)

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Not identified

Lymph Nodes:

Perinodal (extracapsular) extension not identified

Metastatic carcinoma in 1 of 1 node. Metastatic focus is 0.15 cm.

8. Parathyroid, right, lower; excision:

-Benign thymic tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 5]
1). The specimen is received fresh for frozen section consultation, labeled "Right paratracheal node" and consists of a portion of pink-tan soft tissue measuring 1.5 cm in greatest dimension. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "To rule out right lower parathyroid" and consists of a portion of pink tan soft tissue measuring 0.4 cm in greatest dimension. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3). The specimen is received fresh for frozen section consultation, labeled "Rule out right upper parathyroid" and consists of a portion of pink-tan soft tissue measuring 0.2 cm in greatest dimension. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

4). The specimen is received fresh for frozen section consultation, labeled "Right superior mediastinal lymph node" and consists of a portion of pink-tan soft tissue measuring 0.8 cm in greatest dimension. The specimen is entirely submitted for frozen section and permanent section.

Summary of sections:

FSC - frozen section control

U--remainder of tissue

5). The specimen is received fresh for frozen section consultation, labeled "Lymph node lateral to the right RLN" and consists of a portion of pink-tan soft tissue measuring 0.7 cm in greatest dimension. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

6). The specimen is received in formalin, labeled "right levels three and four lymph nodes, neck" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph node

7). The specimen is received in formalin, labeled "total thyroidectomy, stitch marks right thyroid lobe" and consists of a 20.5 g thyroid with a stitch marking the right superior lobe. The right lobe measures 4.8 x 3.1 x 1.8 cm with a 3.2 x 1.9 x 0.7 cm anteriorly attached portion of muscle, the left lobe measures 4.2 x 3 x 1.5 cm and the isthmus measures 2.3 x 1.8 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The specimen is previously inked blue anterior black posterior. Sectioning reveals a 2.5 x 1.4 x 1 cm ovoid, tan-white to tan-white, mottled, focally encapsulated nodule in the right mid pole which abuts both the anterior and posterior capsular aspects. In the upper right-pole is a tan-white, unencapsulated nodule which abuts the posterior capsular aspect. The remaining thyroid parenchyma is red tan and beefy. Representative sections are submitted.

Summary of sections:

RLN - right lobe nodule

RL - right lobe

[page 4 of 5]
LL - left lobe
IS - isthmus

8). The specimen is received fresh, labeled "Rule out right lower parathyroid" and consists of an irregular tan-gray soft tissue measuring 0.9 x 0.6 x 0.2 cm. The specimen is entirely submitted.

Summary of sections:
U -undesignated

Summary of Sections:

Part 1: Right paratracheal node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: To rule out right lower parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Rule out right upper parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: Right superior mediastinal lymph node (fs)

Block	Sect. Site	PCs
1	FSC	1
1	U	1

Part 5: Lymph node lateral to the right RLN (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 6: Right levels 3 and 4 lymph nodes, neck

Block	Sect. Site	PCs
1	BLN	2
2	LN	6

Part 7: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
3	LL	9
2	RL	4
9	RLN	10

Part 8: Rule out right lower parathyroid

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 5 of 5]
1. Frozen section diagnosis: Right paratracheal node(fs): Suspect papillary thyroid carcinoma
Permanent diagnosis: same
2. Frozen section diagnosis: To rule out right lower parathyroid (fs): Lymphoid versus parathyroid tissue, defer
Permanent diagnosis: see final
3. Frozen section diagnosis: Rule out right upper parathyroid (fs): Parathyroid tissue
Permanent diagnosis: same
4. Frozen section diagnosis: Right superior mediastinal lymph node (fs): Papillary thyroid carcinoma
Permanent diagnosis: same
5. Frozen section diagnosis: Lymph node lateral to the right RLN (fs): Suspicious for carcinoma
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 9f1b8fa9-f37f-4d8c-b721-a253d6edb7eb (TCGA-DJ-A3V8.DB6D3411-CF40-470F-8BE5-E4AC3CCD8437.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).